Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012418-09A.2 (aliquot TARGET-15-SJMPAL012418-09A.2-01D) from TARGET case TARGET-15-SJMPAL012418, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,940 days).
Specimen TARGET-15-SJMPAL012418-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74bcfb77-e9d3-43ae-a118-02b0b448d85f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012418-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012418-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dae577a-0c6f-4a7c-82d9-4fcc35cf1387

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2, varscan2
- MSL2 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.525); catalogued as rs1428378462; called by muse, varscan2
- NME8 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52257602, COSV99553734; called by muse, mutect2, varscan2
- NME8 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254074; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 32/59 reads (54%) | catalogued as rs780417788; called by mutect2, varscan2
- WT1 | c.1303+5G>C | Splice Region (SNP) | VAF 98/172 reads (57%) | catalogued as CS115106; called by muse, varscan2
- ASTN2 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ASXL2 | c.2751_2752insCCTG p.S918Pfs*9 | Frame Shift Ins (INS) | VAF 39/91 reads (43%) | called by mutect2, pindel, varscan2
- CCDC171 | c.2045C>A p.A682E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRTAP | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- FCGBP | c.11104G>T p.A3702S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.074); called by muse, mutect2
- GC | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- NBAS | c.3846G>A p.Q1282= | Silent (SNP) | VAF 106/198 reads (54%) | called by muse, mutect2, varscan2
- POTEH | c.258C>T p.H86= | Silent (SNP) | VAF 87/437 reads (20%) | catalogued as rs370869918; called by muse, mutect2, varscan2
- MST1L | n.1145C>T | RNA (SNP) | VAF 18/165 reads (11%) | catalogued as rs773653735; called by muse, mutect2, varscan2
